Somatic mutation profile of tumor specimen TCGA-43-2578-01A (aliquot TCGA-43-2578-01A-01W-0877-08) from TCGA case TCGA-43-2578, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.5 years (21,747 days).
Specimen TCGA-43-2578-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 457cd5c1-38a3-4e00-9f84-ba570a44d97f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-2578-11A (Solid Tissue Normal), aliquot TCGA-43-2578-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4777cbc2-241b-418a-95d9-d06dc636fa3f

The open-access MAF lists 321 somatic variants for this specimen: 240 protein-altering or splice-affecting, 69 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 212, Silent 69, Nonsense Mutation 12, RNA 7, Splice Site 7, Frame Shift Del 5, Splice Region 3, 5'Flank 2, Intron 2, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 98/237 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as CM142087, HM971504, COSV64288951, COSV64296078, COSV64302138; called by muse, mutect2, varscan2
- TTR | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1254341785, COSV52701622, COSV99379470; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.001); catalogued as COSV52629089; called by muse, mutect2, varscan2
- ABCC1 | c.1964G>T p.R655M | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as COSV60687438; called by muse, mutect2, varscan2
- ABCG5 | c.968A>T p.Q323L | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV53211352; called by muse, mutect2, varscan2
- AC004922.1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 94/160 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV99501256; called by muse, varscan2
- ACCSL | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 148/579 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1300284216, COSV66581475; called by muse, varscan2
- ACSM4 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs749254594, COSV68068045; called by muse, mutect2
- ADAMTS8 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV57294148; called by muse, mutect2, varscan2
- ADGRG4 | c.7237A>T p.R2413* | Nonsense Mutation (SNP) | VAF 48/524 reads (9%) | catalogued as COSV54958325; called by muse, mutect2
- ALG10B | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs1218991576, COSV100439817, COSV58142197; called by muse, mutect2, varscan2
- ALPG | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54966486; called by muse, mutect2, varscan2
- ANKRD30A | c.618C>A p.C206* (on ENST00000611781; = p.C150* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 58/211 reads (27%) | catalogued as COSV64612389; called by muse, mutect2, varscan2
- ANO10 | c.406A>T p.R136* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as COSV52732021; called by muse, mutect2, varscan2
- ANO5 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749374398, COSV100201748, COSV61086066; called by muse, mutect2, varscan2
- ARHGAP30 | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV63517039; called by muse, mutect2, varscan2
- ARRDC1 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58376295; called by muse, varscan2
- ASXL3 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52468544; called by muse, mutect2, varscan2
- ATAD2 | c.3031A>T p.K1011* | Nonsense Mutation (SNP) | VAF 90/496 reads (18%) | catalogued as COSV54881709; called by muse, mutect2, varscan2
- ATG2A | c.2017C>G p.L673V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV65967121; called by muse, mutect2, varscan2
- ATG2A | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV65967122, COSV65967328; called by muse, varscan2
- ATP11C | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV59565952; called by muse, mutect2, varscan2
- BEST3 | c.1729A>T p.N577Y | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV58302161; called by muse, mutect2, varscan2
- BRI3BP | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.181); catalogued as rs769412405, COSV58296372; called by muse, mutect2, varscan2
- C1orf94 | c.637G>T p.A213S (on ENST00000488417 / NM_001134734.2; = p.A23S on NM_032884.5) | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV64914301; called by muse, mutect2, varscan2
- C5AR2 | c.607A>G p.I203V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57256446; called by muse, mutect2, varscan2
- CACNA1A | c.3137C>A p.P1046H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV64193815, COSV64200248; called by muse, mutect2, varscan2
- CACNA1F | c.665-1G>T p.X222_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | catalogued as COSV59904960; called by muse, mutect2, varscan2
- CACNA1I | c.367T>G p.F123V | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV60810651, COSV60820140; called by muse, mutect2, varscan2
- CCDC180 | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as rs1204130611, COSV63831266; called by muse, mutect2, varscan2
- CCDC28B | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV52209095; called by muse, mutect2, varscan2
- CD40LG | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 53/470 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV65698638; called by muse, mutect2, varscan2
- CD86 | c.102G>T p.E34D (on ENST00000330540 / NM_175862.5; = p.E28D on NM_006889.4) | Missense Mutation (SNP) | VAF 78/476 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.144); catalogued as COSV52607390; called by muse, mutect2, varscan2
- CFAP47 | c.5096C>A p.A1699E | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV57974378; called by muse, mutect2, varscan2
- CFAP61 | c.2322G>C p.Q774H | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs772984036, COSV55632757; called by muse, mutect2, varscan2
- COG6 | c.1037T>A p.V346D | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV62996355; called by muse, mutect2, varscan2
- COL6A6 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV62027503; called by muse, mutect2, varscan2
- CORIN | c.88A>G p.M30V | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1446435278, COSV56692936; called by muse, mutect2
- CSRNP3 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58779485; called by muse, mutect2, varscan2
- CTAGE1 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as COSV66943728; called by muse, mutect2, varscan2
- CTAGE6 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV101417841; called by muse, mutect2, varscan2
- CTSC | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57058372; called by muse, mutect2
- CUBN | c.8233G>C p.D2745H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64717959; called by mutect2, varscan2
- CYFIP1 | c.3282G>C p.E1094D | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV100488936, COSV57410665; called by muse, mutect2, varscan2
- CYP7B1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 63/209 reads (30%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.82); catalogued as COSV59583230, COSV59590216; called by muse, mutect2, varscan2
- DDI1 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56380873; called by muse, mutect2, varscan2
- DLEC1 | c.515G>T p.S172I | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV57300918; called by muse, mutect2, varscan2
- DNAJC10 | c.1989G>T p.W663C | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899189; called by muse, mutect2, varscan2
- DQX1 | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101099103, COSV66353281; called by muse, mutect2, varscan2
- DUS3L | c.961C>G p.R321G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57832190, COSV57833543; called by mutect2, varscan2
- EPB41L3 | c.1507-2A>T p.X503_splice | Splice Site (SNP) | VAF 29/83 reads (35%) | catalogued as rs778279169, COSV59456507; called by muse, mutect2, varscan2
- EPHB3 | c.2152G>T p.A718S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV57804299, COSV57806631; called by muse, mutect2, varscan2
- EPS15 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65542867, COSV65544492; called by muse, mutect2, varscan2
- ERCC6L | c.3578C>G p.A1193G | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.451); catalogued as COSV57820961; called by muse, mutect2, varscan2
- EYA4 | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 117/413 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM154547, COSV62058091; called by muse, mutect2, varscan2
- F10 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV65022061; called by muse, varscan2
- F9 | c.1255G>T p.V419L | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as COSV54380772; called by muse, mutect2, varscan2
- FAM161B | c.278C>A p.A93E (on ENST00000651776; = p.A30E on NM_152445.3) | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.541); catalogued as COSV53179030, COSV53179849; called by muse, mutect2, varscan2
- FAM47B | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV61454463; called by muse, mutect2, varscan2
- FAM47C | c.1447G>T p.V483L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.784); catalogued as COSV63727228, COSV63729490; called by muse, mutect2
- FANCB | c.2392G>T p.V798F | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.196); catalogued as COSV60760252; called by muse, mutect2, varscan2
- FAP | c.1952C>A p.S651Y | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51862741; called by muse, mutect2, varscan2
- FMOD | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV61610163; called by muse, mutect2, varscan2
- FMR1 | c.201G>T p.V67= | Splice Region (SNP) | VAF 57/621 reads (9%) | catalogued as COSV54424719; called by muse, mutect2
- FOXO4 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58575489; called by muse, mutect2
- G6PD | c.22A>T p.S8C | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as COSV54838640; called by muse, mutect2
- GALNT5 | c.1495A>T p.S499C | Missense Mutation (SNP) | VAF 83/543 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52038359; called by muse, mutect2, varscan2
- GHSR | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53839851; called by muse, mutect2
- GIMAP5 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 96/281 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57530093; called by muse, mutect2, varscan2
- GJB4 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs80358212, CM035047, COSV100258328, COSV58356373; called by muse, mutect2, varscan2
- GLYATL1 | c.634G>T p.G212C (on ENST00000317391 / NM_001354699.1; = p.G243C on NM_080661.4) | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100265293; called by muse, mutect2, varscan2
- GPATCH1 | c.1387A>T p.R463W | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV50116794; called by muse, mutect2, varscan2
- GPR34 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV59368103; called by muse, mutect2, varscan2
- GPRASP1 | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV64355800; called by muse, mutect2, varscan2
- GRM8 | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV100281891, COSV58832977; called by muse, mutect2, varscan2
- GUCY1A2 | c.900T>A p.N300K | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56489461, COSV99972307; called by muse, mutect2, varscan2
- H4C3 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs748976885, COSV58090704; called by muse, mutect2, varscan2
- HEPH | c.2843C>G p.P948R (on ENST00000343002; = p.P681R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV100294524, COSV57960255, COSV57965431; called by muse, mutect2
- IGKV1-12 | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 127/1086 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1359904035; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1331A>T p.Y444F | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV56269277; called by muse, mutect2, varscan2
- IQCG | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV54562816; called by muse, varscan2
- IQGAP3 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV63252230; called by muse, mutect2, varscan2
- IRS4 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.859); catalogued as COSV64534224; called by mutect2, varscan2
- ITGA2 | c.1487G>C p.C496S | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV56860911; called by muse, mutect2, varscan2
- KAT2B | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV55430434; called by muse, mutect2
- KCNJ3 | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54537515; called by muse, mutect2, varscan2
- KCNMA1 | c.2361G>T p.R787S (on ENST00000286628 / NM_001161352.2; = p.R729S on NM_002247.4) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.366); catalogued as COSV54230590, COSV99699178; called by muse, mutect2, varscan2
- KEAP1 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50262252, COSV50294540, COSV99407448; called by muse, mutect2, varscan2
- KIAA1109 | c.12407C>T p.S4136L | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV52677056; called by muse, mutect2, varscan2
- KMT2A | c.5745C>A p.D1915E | Missense Mutation (SNP) | VAF 115/488 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as COSV63286831; called by muse, mutect2, varscan2
- KNCN | c.145G>T p.V49F | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as COSV99606287; called by muse, mutect2, varscan2
- KRTAP12-3 | c.120C>A p.C40* | Nonsense Mutation (SNP) | VAF 132/268 reads (49%) | catalogued as COSV59966169; called by muse, mutect2, varscan2
- KRTAP27-1 | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV67001129; called by muse, mutect2, varscan2
- LAMA1 | c.5008+1G>A p.X1670_splice | Splice Site (SNP) | VAF 55/201 reads (27%) | catalogued as COSV67538673; called by muse, mutect2, varscan2
- LARGE1 | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as COSV61661964, COSV61663459, COSV61672863; called by muse, mutect2
- LDB2 | c.996C>A p.N332K | Missense Mutation (SNP) | VAF 90/279 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs748150349, COSV58771418; called by muse, mutect2, varscan2
- LINGO2 | c.229T>C p.F77L | Missense Mutation (SNP) | VAF 91/372 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.274); catalogued as COSV58060488; called by muse, varscan2
- LPXN | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1245609473, COSV67717332; called by muse, mutect2, varscan2
- LSG1 | c.867G>C p.R289S | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54570776, COSV99503202; called by muse, mutect2, varscan2
- MAGEC2 | c.311G>C p.C104S | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV55999672; called by muse, varscan2
- MAML2 | c.1495G>T p.G499W | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV73263749; called by muse, mutect2, varscan2
- MAP1LC3C | c.400A>T p.R134W | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV61803790; called by muse, mutect2, varscan2
- MARCHF6 | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs779813143, COSV56882379; called by muse, mutect2
- MB21D2 | c.902G>A p.C301Y | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.425); catalogued as COSV66663946, COSV66664278; called by muse, mutect2, varscan2
- MED23 | c.3869A>G p.Y1290C | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV63433175; called by muse, mutect2, varscan2
- MEGF11 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56545554; called by muse, mutect2
- MEPE | c.556T>C p.Y186H | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.392); catalogued as rs768622509, COSV63073080; called by muse, mutect2, varscan2
- MIA3 | c.2215G>T p.A739S | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60513942; called by muse, mutect2, varscan2
- MKRN3 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58808648; called by muse, mutect2, varscan2
- MLH1 | c.1460G>T p.R487L | Missense Mutation (SNP) | VAF 158/487 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs587778917, COSV51619099, COSV51621609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP9 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV63434169; called by muse, varscan2
- MOGAT2 | c.209A>T p.H70L | Missense Mutation (SNP) | VAF 191/816 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV52220025; called by muse, mutect2, varscan2
- MS4A3 | c.625T>A p.S209T | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV53936479; called by muse, mutect2
- MSR1 | c.1232C>A p.P411Q | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV50514527; called by muse, mutect2, varscan2
- MUC16 | c.12311C>G p.S4104* | Nonsense Mutation (SNP) | VAF 98/315 reads (31%) | catalogued as COSV67472336; called by muse, mutect2, varscan2
- MYOM1 | c.4906G>A p.V1636M | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773263720, COSV55293391; called by muse, mutect2, varscan2
- MYRF | c.941T>A p.I314N (on ENST00000278836 / NM_001127392.3; = p.I305N on NM_013279.4) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.454); catalogued as COSV53889774; called by muse, mutect2, varscan2
- MYT1 | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV60501110, COSV60507115; called by muse, varscan2
- NBR1 | c.2827A>T p.N943Y | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57833123; called by muse, mutect2, varscan2
- NCK2 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51892129; called by muse, mutect2, varscan2
- NCOR1 | c.59A>T p.Y20F | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51959192, COSV51978110; called by muse, mutect2, varscan2
- NETO2 | c.1561A>T p.I521L | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57453343; called by muse, mutect2, varscan2
- NEXMIF | c.4257C>A p.N1419K | Missense Mutation (SNP) | VAF 79/719 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV50038217; called by muse, mutect2, varscan2
- NLGN1 | c.859+1G>T p.X287_splice | Splice Site (SNP) | VAF 39/115 reads (34%) | catalogued as COSV64336235; called by muse, mutect2, varscan2
- NLGN1 | c.2314G>T p.D772Y | Missense Mutation (SNP) | VAF 92/504 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64336242; called by muse, mutect2, varscan2
- NLGN3 | c.1486C>A p.R496S (on ENST00000358741 / NM_181303.2; = p.R476S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV100704683; called by muse, mutect2, varscan2
- NLGN3 | c.2519C>A p.P840H (on ENST00000358741 / NM_181303.2; = p.P820H on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62443654; called by muse, varscan2
- NUP133 | c.1584A>T p.Q528H | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54572262; called by muse, mutect2, varscan2
- OCRL | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.531); catalogued as COSV63980597; called by muse, mutect2
- OLFM1 | c.183G>T p.Q61H (on ENST00000371793 / NM_001282611.2; = p.Q43H on NM_006334.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52962524; called by mutect2, varscan2
- OOEP | c.231C>A p.S77R | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV64859302; called by muse, mutect2, varscan2
- OR2T33 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 106/301 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58815741; called by muse, mutect2, varscan2
- OR2W1 | c.56A>G p.N19S | Missense Mutation (SNP) | VAF 62/395 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV65851659; called by muse, mutect2, varscan2
- OR4C15 | c.943C>G p.P315A (on ENST00000314644; = p.P261A on NM_001001920.2) | Missense Mutation (SNP) | VAF 183/795 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.792); catalogued as COSV58952339, COSV58953315; called by muse, mutect2, varscan2
- OR4Q3 | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV59178933; called by muse, mutect2, varscan2
- OR51T1 | c.635A>T p.D212V | Missense Mutation (SNP) | VAF 82/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59025870; called by muse, mutect2, varscan2
- OR56A3 | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 99/303 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV61569291; called by muse, mutect2, varscan2
- OR5D14 | c.662T>A p.V221D | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV59456740; called by muse, mutect2, varscan2
- OR7C2 | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV50180796; called by muse, mutect2, varscan2
- OR8D4 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58429485, COSV58430624; called by muse, mutect2, varscan2
- PCDH15 | c.4909T>A p.S1637T | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated, low confidence (0.37); catalogued as COSV64701065; called by muse, mutect2, varscan2
- PCDHGA3 | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.05); catalogued as COSV53917549, COSV53964395; called by muse, mutect2, varscan2
- PGK1 | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV64832139; called by muse, mutect2, varscan2
- PIGT | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 123/521 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54126766; called by muse, mutect2, varscan2
- PIK3CG | c.777G>T p.M259I | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV63247013, COSV63249282; called by muse, mutect2, varscan2
- PKHD1L1 | c.7937C>A p.A2646E | Missense Mutation (SNP) | VAF 119/941 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV65745005; called by muse, mutect2, varscan2
- PLXNA4 | c.1162G>T p.V388L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as COSV58132663; called by muse, varscan2
- PLXNA4 | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.625); catalogued as COSV58132706; called by muse, varscan2
- PNMA5 | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62625742; called by muse, mutect2, varscan2
- PNMA8B | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66536804; called by muse, mutect2
- POP1 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 161/719 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV62893083; called by muse, mutect2, varscan2
- POU2F3 | c.769+2T>A p.X257_splice | Splice Site (SNP) | VAF 6/125 reads (5%) | catalogued as COSV52794624; called by muse, mutect2
- PRICKLE3 | c.954C>T p.I318= | Splice Region (SNP) | VAF 60/248 reads (24%) | catalogued as rs376833620, COSV66234151; called by muse, mutect2, varscan2
- PRKCB | c.269A>T p.D90V | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs750901145, COSV57783485; called by muse, mutect2, varscan2
- PRKDC | c.8024C>T p.S2675F | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs369642176; called by muse, mutect2, varscan2
- PRR11 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51877072, COSV99231792; called by muse, mutect2, varscan2
- PSG7 | c.45G>C p.W15C | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV68445394; called by muse, mutect2, varscan2
- PTPN4 | c.1414A>G p.K472E | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.142); catalogued as COSV55302849; called by muse, mutect2, varscan2
- PTX3 | c.1087A>T p.I363F | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV55821758; called by muse, mutect2, varscan2
- RAB39B | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 36/610 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV101034968, COSV65624513; called by muse, mutect2
- RARS1 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as rs757507711, COSV51564056; called by muse, mutect2, varscan2
- RB1 | c.1901C>G p.S634* | Nonsense Mutation (SNP) | VAF 38/167 reads (23%) | catalogued as CM961233, COSV57296525, COSV57302654; called by muse, mutect2, varscan2
- RGS6 | c.1097G>T p.W366L | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59580080; called by muse, mutect2, varscan2
- RNF181 | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57818061; called by muse, mutect2, varscan2
- RNF207 | c.1505G>C p.R502P | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV65007802; called by muse, varscan2
- ROR2 | c.2433G>A p.M811I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as COSV65219953; called by muse, mutect2, varscan2
- RPGR | c.1741G>T p.D581Y | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100139914; called by mutect2, varscan2
- RPS6KB2 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57052066; called by muse, mutect2, varscan2
- SALL1 | c.3494C>A p.T1165N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV51758851; called by muse, mutect2, varscan2
- SCN10A | c.652A>T p.R218* | Nonsense Mutation (SNP) | VAF 187/505 reads (37%) | catalogued as COSV71861761; called by muse, varscan2
- SEMG2 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 79/439 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs368513832; called by muse, mutect2, varscan2
- SFMBT2 | c.1214G>T p.S405I | Missense Mutation (SNP) | VAF 129/437 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV62810916; called by muse, mutect2, varscan2
- SGIP1 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV52771012; called by muse, mutect2, varscan2
- SLAMF7 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.355); catalogued as rs753606290, COSV63563364; called by muse, mutect2, varscan2
- SLC24A4 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 36/567 reads (6%) | catalogued as COSV54114496; called by muse, mutect2
- SLC6A6 | c.1058A>G p.Q353R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as COSV62650320; called by muse, mutect2, varscan2
- SLC9A2 | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV52132966; called by muse, mutect2, varscan2
- SLITRK3 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53849238; called by muse, mutect2, varscan2
- SMPD2 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.203); catalogued as COSV57805755; called by muse, mutect2, varscan2
- SOBP | c.171G>C p.E57D | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as COSV57998898; called by muse, mutect2, varscan2
- SPATA21 | c.86C>G p.A29G | Missense Mutation (SNP) | VAF 234/983 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59187341; called by muse, mutect2, varscan2
- SPATA31E1 | c.2927T>C p.V976A | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.225); catalogued as COSV57790116, COSV57792526; called by mutect2, varscan2
- SPIC | c.176C>G p.T59R | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.203); catalogued as COSV54691660; called by muse, mutect2, varscan2
- SSX1 | c.29G>T p.R10I | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV65355678; called by muse, mutect2
- ST7 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 71/469 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55386560; called by muse, mutect2, varscan2
- SYMPK | c.2490G>T p.P830= | Splice Region (SNP) | VAF 9/61 reads (15%) | catalogued as COSV55612589, COSV55615816; called by muse, mutect2, varscan2
- SYNE1 | c.11441G>T p.G3814V (on ENST00000367255 / NM_182961.4; = p.G3799V on NM_033071.3) | Missense Mutation (SNP) | VAF 140/423 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as COSV55005209; called by muse, mutect2, varscan2
- SYNE1 | c.4009-1G>T p.X1337_splice (on ENST00000367255 / NM_182961.4; = p.X1344_splice on NM_033071.3) | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV55005240; called by muse, mutect2, varscan2
- TAF1 | c.1886T>C p.M629T (on ENST00000373790 / NM_138923.4; = p.M650T on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/471 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV52108129, COSV52115532; called by muse, mutect2
- TAS2R19 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 112/575 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs770713225, COSV66828505; called by muse, mutect2, varscan2
- TAS2R41 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV68765403; called by muse, mutect2, varscan2
- TCOF1 | c.1136A>T p.K379M (on ENST00000377797 / NM_001135243.1; = p.K302M on NM_000356.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60349541; called by muse, mutect2, varscan2
- TIE1 | c.1201A>T p.I401F | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.956); catalogued as COSV65250001; called by muse, mutect2, varscan2
- TMEM161B | c.1402G>C p.A468P | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56931393; called by muse, mutect2, varscan2
- TMEM25 | c.229T>A p.S77T | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as COSV57097011; called by muse, mutect2, varscan2
- TRAPPC8 | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768476324, COSV51967302; called by muse, mutect2, varscan2
- TRIO | c.6750T>G p.I2250M | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV59990562; called by muse, mutect2, varscan2
- TRIOBP | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV60378984; called by muse, mutect2, varscan2
- TRPS1 | c.1051G>T p.E351* (on ENST00000220888 / NM_001330599.2; = p.E364* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 59/164 reads (36%) | catalogued as CM1514912, COSV55244727; called by muse, mutect2, varscan2
- TSHZ2 | c.1522G>C p.D508H | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV61589307; called by muse, mutect2, varscan2
- TUT1 | c.2324G>A p.W775* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV53470393; called by muse, mutect2, varscan2
- TXNDC2 | c.576G>C p.E192D (on ENST00000306084 / NM_001098529.2; = p.E125D on NM_032243.6) | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as COSV60153823; called by muse, mutect2
- UFL1 | c.1048A>T p.S350C | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV65149991; called by muse, mutect2, varscan2
- UGT1A6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 28/148 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.095); catalogued as COSV59390521; called by muse, mutect2
- UGT2B11 | c.772A>C p.M258L | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV71423504; called by muse, mutect2
- UNC5C | c.764T>A p.V255D | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV71660389; called by muse, mutect2, varscan2
- UNC5D | c.2689C>A p.P897T | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54801415; called by muse, mutect2
- UPP1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as rs368798686, COSV57977755; called by muse, mutect2, varscan2
- VPS41 | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV59649604; called by muse, mutect2, varscan2
- WDR64 | c.1255A>C p.M419L | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV63796764; called by muse, mutect2, varscan2
- YBX1 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs777886244; called by muse, varscan2
- ZFHX4 | c.1561G>A p.G521S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.073); catalogued as rs763235796, COSV50998747; called by muse, mutect2, varscan2
- ZNF136 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59710998; called by muse, mutect2, varscan2
- ZNF28 | c.1160A>T p.E387V | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV60423524; called by muse, mutect2, varscan2
- ZNF362 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV65031502; called by muse, mutect2, varscan2
- ZNF41 | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57443311; called by muse, mutect2, varscan2
- ZNF423 | c.853G>A p.E285K (on ENST00000563137 / NM_001379286.1; = p.E277K on NM_015069.4) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as rs1313395769, COSV52191771; called by muse, mutect2
- ZNF574 | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs778036814, COSV55904215; called by mutect2, varscan2
- ZNF687 | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55018112; called by muse, mutect2, varscan2
- ZZZ3 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 95/331 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV66233443; called by muse, mutect2, varscan2
- AHNAK2 | c.1881_1890del p.R628Kfs*3 | Frame Shift Del (DEL) | VAF 59/273 reads (22%) | called by mutect2, pindel, varscan2
- CACNB1 | c.1750A>C p.N584H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CSMD3 | c.9042del p.S3015Lfs*14 (on ENST00000297405 / NM_001363185.1; = p.S2846Lfs*14 on NM_052900.3) | Frame Shift Del (DEL) | VAF 63/148 reads (43%) | called by mutect2, pindel, varscan2
- DOCK11 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 10/342 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.901); called by muse, mutect2
- HAPLN1 | c.818A>G p.D273G | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2
- HTR1A | c.883del p.V295Cfs*50 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by pindel, varscan2
- IGHV3-66 | c.92T>G p.I31S | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); called by mutect2, varscan2
- KCNU1 | c.198A>C p.E66D | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- MED13L | c.2840C>T p.S947F | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); called by muse, mutect2
- MELTF | c.254_258del p.A85Efs*36 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- MSMB | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, varscan2
- MXRA5 | c.2802del p.T935Pfs*59 | Frame Shift Del (DEL) | VAF 37/286 reads (13%) | called by mutect2, pindel, varscan2
- NSDHL | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 56/978 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- OR2T12 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- PLA2G15 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRMT3 | c.1487-7_1508del p.X496_splice | Splice Site (DEL) | VAF 24/122 reads (20%) | called by mutect2, pindel
- SENP7 | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- SPIN3 | c.372G>T p.L124F | Missense Mutation (SNP) | VAF 44/941 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); called by muse, mutect2
- THBS2 | c.3434A>T p.Y1145F | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.049); called by mutect2, varscan2
- TNFSF11 | c.626A>C p.N209T | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- AARD | c.147C>T p.A49= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs1186116583, COSV65600033; called by muse, mutect2, varscan2
- ABCA4 | c.6648G>A p.A2216= | Silent (SNP) | VAF 50/181 reads (28%) | catalogued as rs779465743, COSV64674270; called by muse, mutect2, varscan2
- ACSM1 | c.72T>A p.P24= | Silent (SNP) | VAF 187/1032 reads (18%) | catalogued as COSV54636599; called by muse, mutect2, varscan2
- AMER1 | c.1269G>T p.L423= | Silent (SNP) | VAF 57/499 reads (11%) | catalogued as COSV57659057; called by muse, mutect2, varscan2
- ARID1B | c.4212G>A p.R1404= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as rs770732982, COSV51665243; called by muse, mutect2, varscan2
- ATP9A | c.1329G>T p.T443= | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as COSV100125283, COSV58767685; called by muse, mutect2, varscan2
- BACE2 | c.1534C>T p.L512= | Silent (SNP) | VAF 61/283 reads (22%) | catalogued as COSV57740295; called by muse, mutect2, varscan2
- BCL6B | c.433C>T p.L145= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV53428189; called by muse, mutect2, varscan2
- CASS4 | c.2289G>T p.A763= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs772143299, COSV64386784, COSV64387957; called by muse, mutect2, varscan2
- CCNB3 | c.711A>C p.A237= | Silent (SNP) | VAF 22/328 reads (7%) | catalogued as COSV52074756; called by muse, mutect2
- CHSY3 | c.2413C>T p.L805= | Silent (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
- CNR1 | c.804C>T p.F268= | Silent (SNP) | VAF 8/181 reads (4%) | catalogued as COSV62990371; called by muse, mutect2
- CTAGE1 | c.1302G>T p.S434= | Silent (SNP) | VAF 39/220 reads (18%) | catalogued as COSV101194516, COSV66945004; called by muse, mutect2, varscan2
- CUL2 | c.513T>G p.R171= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV66079465; called by muse, mutect2, varscan2
- CYP7B1 | c.1185C>A p.I395= | Silent (SNP) | VAF 47/259 reads (18%) | catalogued as COSV59590205; called by muse, mutect2, varscan2
- DHCR7 | c.297C>G p.L99= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV62795614; called by mutect2, varscan2
- DHX58 | c.753G>T p.R251= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV52426305; called by muse, mutect2, varscan2
- DIAPH2 | c.2697A>G p.E899= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as COSV61273296; called by muse, mutect2
- DNAH3 | c.5979C>A p.P1993= | Silent (SNP) | VAF 61/309 reads (20%) | catalogued as COSV54527378; called by muse, mutect2, varscan2
- ECSIT | c.195C>G p.P65= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV52939700; called by muse, mutect2, varscan2
- EIF1AD | c.138G>A p.G46= | Silent (SNP) | VAF 37/179 reads (21%) | catalogued as COSV56463740; called by muse, mutect2, varscan2
- EPHA4 | c.792T>A p.A264= | Silent (SNP) | VAF 109/262 reads (42%) | catalogued as COSV56035388; called by muse, mutect2, varscan2
- F11R | c.21C>G p.V7= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV57038057; called by muse, mutect2, varscan2
- FAM47A | c.513G>A p.K171= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV60497487; called by muse, mutect2, varscan2
- FAM83C | c.2040G>T p.L680= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV65583365; called by muse, mutect2, varscan2
- FAS | c.171A>G p.Q57= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs1163621042; called by muse, mutect2
- HCN1 | c.1206T>C p.S402= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV57515934; called by muse, mutect2, varscan2
- IGSF9B | c.2394C>T p.D798= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs376960993; called by muse, mutect2
- IVD | c.411C>T p.I137= (on ENST00000651168; = p.I134= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1357609658, COSV51099484; called by muse, mutect2, varscan2
- KLHL40 | c.939C>G p.G313= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV55134926; called by muse, mutect2, varscan2
- LAMB4 | c.3114G>A p.G1038= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV99226023; called by muse, mutect2, varscan2
- LRRC10 | c.735A>G p.P245= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV64060448; called by muse, mutect2
- MAGEB1 | c.495G>A p.L165= | Silent (SNP) | VAF 110/187 reads (59%) | catalogued as COSV66775881; called by muse, mutect2, varscan2
- MAGEC1 | c.1107C>A p.P369= | Silent (SNP) | VAF 34/400 reads (9%) | catalogued as COSV99595557; called by muse, mutect2
- MCM6 | c.1110G>T p.L370= | Silent (SNP) | VAF 50/238 reads (21%) | catalogued as COSV51466087, COSV51466952; called by muse, mutect2, varscan2
- MYH6 | c.588C>A p.A196= | Silent (SNP) | VAF 109/229 reads (48%) | catalogued as COSV62451581; called by muse, mutect2, varscan2
- NLRP12 | c.1197C>A p.T399= | Silent (SNP) | VAF 70/248 reads (28%) | catalogued as COSV100145197; called by mutect2, varscan2
- NMNAT3 | c.234C>A p.I78= (on ENST00000296202 / NM_001320512.1; = p.I41= on NM_178177.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV56156780, COSV56159911; called by muse, mutect2, varscan2
- NOBOX | c.900T>C p.D300= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as COSV56195103; called by muse, mutect2, varscan2
- NOMO1 | c.813G>T p.T271= | Silent (SNP) | VAF 76/377 reads (20%) | catalogued as rs758903904, COSV99814486; called by muse, mutect2, varscan2
- NOX3 | c.519A>C p.A173= | Silent (SNP) | VAF 77/264 reads (29%) | catalogued as COSV50153964; called by muse, mutect2, varscan2
- NPC1L1 | c.2521C>T p.L841= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV56926101; called by muse, mutect2, varscan2
- NRAP | c.507C>T p.S169= | Silent (SNP) | VAF 60/302 reads (20%) | catalogued as rs138386465, COSV63491315; called by muse, varscan2
- NVL | c.1590G>A p.R530= | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as COSV55873071; called by muse, mutect2, varscan2
- OR8K5 | c.138C>T p.I46= | Silent (SNP) | VAF 50/285 reads (18%) | catalogued as COSV100537154, COSV57889393; called by muse, mutect2, varscan2
- OR9G1 | c.429G>A p.L143= | Silent (SNP) | VAF 83/624 reads (13%) | catalogued as rs1347674084, COSV56447900, COSV56451114; called by muse, varscan2
- PHLDB2 | c.2484A>G p.K828= (on ENST00000393925 / NM_001134439.2; = p.K785= on NM_145753.2) | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV67312269; called by muse, varscan2
- PNMA8A | c.1254T>G p.S418= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV58137407; called by muse, mutect2, varscan2
- PPP1R9A | c.696G>T p.G232= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV56896328; called by muse, mutect2, varscan2
- PRAF2 | c.168C>G p.L56= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV59876210, COSV59876306; called by muse, mutect2, varscan2
- RBM42 | c.336C>T p.P112= | Silent (SNP) | VAF 125/441 reads (28%) | catalogued as rs1049663709, COSV52897882; called by muse, mutect2, varscan2
- RGL3 | c.1662G>A p.G554= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV66509325; called by muse, mutect2, varscan2
- RTL8B | c.66C>T p.R22= | Silent (SNP) | VAF 33/253 reads (13%) | catalogued as COSV66954329; called by muse, mutect2, varscan2
- SCG3 | c.843T>C p.Y281= | Silent (SNP) | VAF 74/201 reads (37%) | catalogued as COSV55021626; called by muse, mutect2, varscan2
- SCN10A | c.1164G>T p.L388= | Silent (SNP) | VAF 83/341 reads (24%) | catalogued as COSV71861760; called by muse, mutect2, varscan2
- SLC7A9 | c.924T>C p.F308= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV50086632; called by muse, mutect2, varscan2
- SPPL3 | c.537C>T p.A179= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs773557756, COSV62232803; called by muse, mutect2
- SSX3 | c.495C>A p.T165= | Silent (SNP) | VAF 158/1986 reads (8%) | catalogued as rs782149886, COSV53644395; called by muse, mutect2
- SUOX | c.1014G>C p.R338= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV56268952; called by muse, mutect2, varscan2
- TAF7L | c.201G>C p.A67= | Silent (SNP) | VAF 81/172 reads (47%) | catalogued as rs748167428, COSV100774185, COSV100774244; called by mutect2, varscan2
- TECTA | c.4287C>A p.S1429= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV50695075, COSV50720911; called by muse, mutect2
- TMEM132E | c.2391G>T p.L797= (on ENST00000321639; = p.L887= on NM_001304438.2) | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV58697828; called by muse, mutect2, varscan2
- TMX4 | c.705T>A p.A235= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as COSV55680984; called by muse, mutect2, varscan2
- VIT | c.1863G>C p.V621= (on ENST00000389975 / NM_001177969.1; = p.V636= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/141 reads (35%) | catalogued as COSV64897012; called by muse, mutect2, varscan2
- VRTN | c.1812C>T p.S604= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV56441564; called by muse, mutect2, varscan2
- XKRX | c.963C>A p.G321= | Silent (SNP) | VAF 48/658 reads (7%) | catalogued as COSV60708348; called by muse, mutect2
- ZNF20 | c.1080A>G p.T360= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV61999628; called by muse, mutect2, varscan2
- ZNF254 | c.906A>G p.A302= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV61642990; called by muse, mutect2, varscan2
- ZNF28 | c.1671G>A p.E557= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as COSV60423517, COSV60425750; called by muse, mutect2, varscan2
- C14orf177 | n.683T>A | RNA (SNP) | VAF 138/275 reads (50%) | catalogued as COSV57901086; called by muse, mutect2, varscan2
- CACNA1C | c.1481+555G>T | Intron (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100216354; called by muse, mutect2, varscan2
- CDH11 | c.1895-591C>G | Intron (SNP) | VAF 5/30 reads (17%) | catalogued as rs747561850, COSV99218150; called by mutect2, varscan2
- DEPDC5 | c.*956G>T | 3'UTR (SNP) | VAF 40/152 reads (26%) | catalogued as COSV56699834; called by muse, mutect2, varscan2
- FOLH1B | n.1928A>T | RNA (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- MAT2B | chr5:163503398 C>T | 5'Flank (SNP) | VAF 58/202 reads (29%) | catalogued as COSV99796646; called by muse, mutect2, varscan2
- MATK | chr19:3789341 C>A | 5'Flank (SNP) | VAF 19/29 reads (66%) | catalogued as COSV100036039; called by muse, mutect2, varscan2
- MIR516A1 | n.77G>C | RNA (SNP) | VAF 70/203 reads (34%) | catalogued as rs1047731138; called by muse, mutect2, varscan2
- MIR518A2 | n.27A>T | RNA (SNP) | VAF 132/250 reads (53%) | called by muse, varscan2
- MIR888 | n.71A>T | RNA (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- SLC35E2A | n.1062G>T | RNA (SNP) | VAF 6/46 reads (13%) | catalogued as COSV55803795; called by muse, mutect2, varscan2
- UBTFL2 | n.354G>C | RNA (SNP) | VAF 14/48 reads (29%) | catalogued as rs1351673887; called by muse, mutect2, varscan2
